Somatic mutation profile of tumor specimen 0DH5VT from CCDI case PBBUAW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: External ear; Age at diagnosis: 4.9 years (1,772 days).
Specimen 0DH5VT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0beb37-e9d3-41eb-b635-5fee268c34d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5UB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/200e2cde-0b39-4a8a-a196-90bc99413ba3

The open-access MAF lists 15 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 3, 3'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 139/932 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774571806, COSV52800715, COSV52802492, COSV52804538; called by muse, varscan2
- NRXN2 | c.4133G>A p.R1378H | Missense Mutation (SNP) | VAF 96/800 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99632166; called by muse, varscan2
- RNF213 | c.8332G>A p.A2778T | Missense Mutation (SNP) | VAF 180/886 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770646963; called by muse, varscan2
- SH3BP2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 64/462 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs372066896; called by muse, varscan2
- RPRD2 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 70/559 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, varscan2
- CDKN2B | c.303G>A p.R101= | Silent (SNP) | VAF 27/223 reads (12%) | called by muse, varscan2
- MUC5AC | c.3906C>T p.S1302= | Silent (SNP) | VAF 60/400 reads (15%) | catalogued as rs1040100016; called by muse, varscan2
- TRPM4 | c.2277C>T p.C759= | Silent (SNP) | VAF 80/764 reads (10%) | called by muse, varscan2
- ZNF709 | c.1188G>A p.Q396= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV67196146; called by muse, varscan2
- ABCA8 | c.3919-32G>A | Intron (SNP) | VAF 35/285 reads (12%) | called by muse, varscan2
- DEDD | chr1:161118049 G>C | 3'Flank (SNP) | VAF 37/287 reads (13%) | catalogued as rs1313576255; called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- PPP1R16B | c.-20C>T | 5'UTR (SNP) | VAF 16/154 reads (10%) | catalogued as rs923075190; called by muse, varscan2
- RPL30 | c.*75T>A | 3'UTR (SNP) | VAF 28/272 reads (10%) | called by muse, varscan2
- SLC12A5 | c.121+11C>A | Intron (SNP) | VAF 38/308 reads (12%) | catalogued as rs764312398; called by muse, varscan2
